Somatic mutation profile of tumor specimen MBCProject_0320_T1_WES (aliquot MBCProject_0320_T1_WES_1) from CMI case MBCProject_0320, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.6 years (20,683 days).
Specimen MBCProject_0320_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a07106ab-0d8f-45f2-b219-b57f3e065174.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0320_SALIVA (Saliva), aliquot MBCProject_0320_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95943dcd-4e9f-4233-bf61-8dce99b9e4f1

The open-access MAF lists 31 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Intron 3, Frame Shift Del 3, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1B1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs145597002; called by mutect2, varscan2
- ARHGEF17 | c.2259C>G p.F753L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as COSV55231275; called by muse, mutect2, varscan2
- GATA3 | c.1275dup p.S426Ifs*81 | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | catalogued as COSV60519172, COSV60519754; called by mutect2, pindel, varscan2
- KLK14 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.159); catalogued as rs1051936869; called by muse, mutect2, varscan2
- MSH2 | c.1580G>C p.C527S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as rs1553366585, COSV99254928; ClinVar: uncertain significance; called by muse, mutect2
- MYH8 | c.5277G>T p.K1759N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101238076, COSV67972497; called by muse, mutect2
- NEXMIF | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs868590828; called by muse, mutect2, varscan2
- RASGRF1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs371901610; called by mutect2, varscan2
- RNF213 | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1292798259; called by muse, mutect2
- ARHGEF17 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL18A1 | c.744del p.S249Afs*20 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- CTTN | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HDX | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- OR51V1 | c.60T>A p.F20L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, varscan2
- PRKAA1 | c.213A>C p.K71N | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC7A7 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2
- STAB1 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYCN | c.293del p.G98Afs*22 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel*, varscan2
- TP53 | c.351del p.T118Qfs*5 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- U2AF2 | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- GRM7 | c.309G>A p.A103= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs765117194; called by muse, mutect2, varscan2
- INTS6 | c.1935C>T p.P645= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as rs561343385, COSV100247087; called by muse, mutect2
- PSAP | c.135G>T p.V45= | Silent (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- RBP7 | c.147T>C p.S49= | Silent (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
- SLC35F1 | c.1113C>T p.R371= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as rs769544097, COSV64505673; called by muse, mutect2, varscan2
- TAF1L | c.336C>T p.I112= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- TBC1D26 | c.249A>G p.A83= | Silent (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- ADH4 | c.19-457C>T | Intron (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- CLDND1 | c.*827C>G | 3'UTR (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- GRIN1 | c.1113+25G>A | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SRGAP2 | c.2505-225C>T | Intron (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2
